Gene-level copy-number profile of tumor specimen TCGA-24-1422-01A from TCGA case TCGA-24-1422, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 82.8 years (30,234 days).
Specimen TCGA-24-1422-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.9b610217-9f59-46d7-ba9d-9d460c659802.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1422-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/75b55e4e-ab12-44a3-9bcf-a30ce73ad18b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 5,007; copy number 2: 20,914; copy number 3: 18,335; copy number 4: 11,396; copy number 5: 3,618; copy number 6: 433; copy number 7: 50; copy number 8: 25; copy number 11: 13; copy number 16: 1; copy number 20: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1422-01A-01D-0472-01): tumor purity 0.64, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:10,948,372–12,058,227, 6 genes (within-gene range 0–1): AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1.
- chr14:42,412,573–42,528,888, 1 gene (within-gene range 0–2): AL450442.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,143 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,859,912–38,965,038, 1 gene, copy number 5 (within-gene range 4–5): AL139260.1.
- chr1:38,885,807–65,761,352, 664 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:234,261,706–235,104,609, 34 genes, copy number 5: AL122008.1, SLC35F3-AS1, AL122008.2, MIR4671, AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2.
- chr2:152,635,268–174,502,312, 291 genes, copy number 5–6 (broad region; genes not listed).
- chr2:188,598,791–192,645,706, 63 genes, copy number 5 (broad region; genes not listed).
- chr2:224,169,664–242,160,153, 384 genes, copy number 5 (broad region; genes not listed).
- chr3:68,633,706–69,123,032, 11 genes, copy number 5: AC096922.1, PSMC1P1, TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3.
- chr3:116,965,112–117,027,039, 2 genes, copy number 5: RNU5E-8P, PTMAP8.
- chr3:128,798,841–174,378,005, 734 genes, copy number 5 (broad region; genes not listed).
- chr3:174,631,823–174,632,064, 1 gene, copy number 5: RN7SKP40.
- chr5:97,089,075–97,437,217, 1 gene, copy number 5 (within-gene range 3–5): LIX1-AS1.
- chr5:97,160,867–127,941,634, 371 genes, copy number 5–6 (broad region; genes not listed).
- chr7:82,589,848–83,649,139, 8 genes, copy number 5 (within-gene range 3–5): MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1.
- chr7:131,892,616–141,888,092, 177 genes, copy number 5 (broad region; genes not listed).
- chr7:141,911,217–141,973,773, 4 genes, copy number 5: OR9N1P, OR9A4, CLEC5A, TAS2R38.
- chr8:67,732,587–80,484,481, 180 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:131,712,512–133,134,903, 18 genes, copy number 5 (within-gene range 4–5): AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1.
- chr10:2,501,600–10,462,361, 144 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:29,159,956–32,104,665, 32 genes, copy number 5–8 (within-gene range 3–8): AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4.
- chr12:39,539,581–41,072,415, 17 genes, copy number 11–20 (within-gene range 3–20): AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1.
- chr13:95,801,580–96,053,482, 1 gene, copy number 6 (within-gene range 4–6): UGGT2.
- chr13:96,090,839–113,864,076, 270 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr18:2,506,628–5,197,503, 58 genes, copy number 5–7 (within-gene range 3–7): AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1.
- chr18:9,020,029–11,670,165, 69 genes, copy number 5 (broad region; genes not listed).
- chr18:26,016,253–29,361,963, 43 genes, copy number 6: SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1.
- chr18:30,713,275–36,279,119, 106 genes, copy number 5–8 (broad region; genes not listed).
- chr18:36,417,055–36,424,185, 1 gene, copy number 5: AC055840.1.
- chr18:37,565,281–41,632,185, 23 genes, copy number 6 (within-gene range 3–6): AC009899.1, MIR4318, RPL12P40, AC108452.1, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1, AC079052.1, KC6.
- chr18:42,089,312–42,691,422, 5 genes, copy number 5: AC087683.1, AC087683.3, LINC00907, RNA5SP454, AC084335.1.
- chr19:10,086,122–15,950,350, 349 genes, copy number 5 (broad region; genes not listed).
- chr20:45,722,347–47,786,616, 64 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr21:45,981,769–46,286,297, 17 genes, copy number 5 (within-gene range 3–5): COL6A1, AP001476.1, AP001476.3, AP001476.2, PSMA6P3, AP001471.1, COL6A2, FTCD, FTCD-AS1, SPATC1L, AP001468.1, LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3.

Autosomal genes at a single copy (total copy number 1): 2,826. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
